Somatic mutation profile of tumor specimen C3N-01200-05 (aliquot CPT0075160012) from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df552346-1f85-41ea-82b0-e876e00b0bae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01200-71 (Blood Derived Normal), aliquot CPT0075240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d15dc0d-1bba-4f6f-a98e-13a697426888

The open-access MAF lists 82 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Intron 12, Frame Shift Del 5, Frame Shift Ins 3, 3'UTR 3, In Frame Del 3, Nonsense Mutation 2, Splice Region 1, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.758dup p.T254Dfs*30 | Frame Shift Ins (INS) | VAF 80/362 reads (22%) | catalogued as rs1553645591; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHEK2 | c.597C>A p.Y199* (on ENST00000382580 / NM_001005735.2; = p.Y156* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 9/169 reads (5%) | catalogued as rs1555926996; ClinVar: pathogenic; called by muse, mutect2
- ATP1A3 | c.1778C>G p.S593C (on ENST00000545399 / NM_001256214.2; = p.S580C on NM_152296.5) | Missense Mutation (SNP) | VAF 77/397 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487252; called by muse, mutect2, varscan2
- BTBD3 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs759996580; called by muse, mutect2, varscan2
- EEA1 | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1172307888; called by muse, mutect2, varscan2
- GLRA3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- KRTAP22-2 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | PolyPhen possibly damaging (0.617); catalogued as COSV66962843; called by muse, mutect2, varscan2
- MBP | c.562C>T p.R188W (on ENST00000355994 / NM_001025101.2; = p.R55W on NM_002385.3) | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766571087; called by mutect2, varscan2
- MICAL2 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- SLC19A1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs776173955, COSV60756989; called by muse, mutect2, varscan2
- AC097518.1 | n.166C>T | Splice Region (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- CASD1 | c.2264T>C p.I755T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASK | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CSMD3 | c.9249T>A p.D3083E (on ENST00000297405 / NM_001363185.1; = p.D2914E on NM_052900.3) | Missense Mutation (SNP) | VAF 48/323 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF7 | c.276_284del p.D93_L95del | In Frame Del (DEL) | VAF 31/157 reads (20%) | called by mutect2, pindel
- DNAH11 | c.11714del p.G3905Vfs*12 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7391del p.G2464Afs*2 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- ELL2 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FOXB2 | c.599dup p.Q201Afs*73 | Frame Shift Ins (INS) | VAF 28/215 reads (13%) | called by pindel, varscan2
- GRIPAP1 | c.380_406del p.A127_G135del | In Frame Del (DEL) | VAF 27/135 reads (20%) | called by mutect2, pindel
- H1-8 | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- HAS3 | c.1227T>G p.I409M | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGDCC4 | c.1801A>C p.I601L | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNG2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KIFAP3 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LAMC3 | c.2048T>G p.F683C | Missense Mutation (SNP) | VAF 113/601 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCE3A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 114/530 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MGAM2 | c.4256A>G p.E1419G | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTMR3 | c.2322del p.L775Sfs*24 | Frame Shift Del (DEL) | VAF 47/302 reads (16%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2
- OR52N5 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2
- PKD1 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PLA2G3 | c.1091T>G p.F364C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- POLE | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- REM1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SALL3 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCAMP3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SETD2 | c.6553G>T p.G2185* | Nonsense Mutation (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- SNX5 | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPANXN5 | c.154_156del p.L52del | In Frame Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- SPART | c.783del p.L262* | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- SPATS2 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- VHL | c.610_614del p.E204Hfs*50 | Frame Shift Del (DEL) | VAF 56/307 reads (18%) | called by mutect2, pindel, varscan2
- VPS35 | c.1499_1500dup p.E501Lfs*9 | Frame Shift Ins (INS) | VAF 39/270 reads (14%) | called by mutect2, pindel, varscan2
- WDR6 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF256 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADCY6 | c.2322C>A p.A774= | Silent (SNP) | VAF 46/193 reads (24%) | catalogued as rs1362941438; called by muse, mutect2, varscan2
- AHNAK | c.6627A>T p.V2209= | Silent (SNP) | VAF 63/361 reads (17%) | called by muse, mutect2, varscan2
- CDK11B | c.1002G>A p.E334= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs1279885928; called by mutect2, varscan2
- CENPE | c.2013A>G p.L671= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99477122; called by muse, mutect2, varscan2
- IFIH1 | c.2532G>A p.E844= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- KCNG2 | c.1254G>A p.Q418= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- MFSD6 | c.1326C>T p.L442= | Silent (SNP) | VAF 53/163 reads (33%) | called by muse, mutect2, varscan2
- MS4A4E | c.126G>A p.R42= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs267603050; called by muse, mutect2, varscan2
- NOTCH3 | c.1335G>A p.T445= | Silent (SNP) | VAF 32/272 reads (12%) | catalogued as rs568403807, COSV54650413; called by muse, mutect2, varscan2
- NPY5R | c.1254T>C p.C418= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- NUP210 | c.1140C>G p.V380= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- PAK4 | c.939C>T p.D313= | Silent (SNP) | VAF 103/479 reads (22%) | catalogued as rs369018322; called by muse, mutect2, varscan2
- PLEKHA4 | c.441G>T p.A147= | Silent (SNP) | VAF 59/315 reads (19%) | catalogued as rs1404611123; called by muse, mutect2, varscan2
- PLXDC2 | c.1395C>A p.L465= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV65904134; called by muse, mutect2, varscan2
- TTN | c.84165A>C p.T28055= (on ENST00000591111; = p.T20631= on NM_003319.4) | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- VEZF1 | c.348C>A p.I116= | Silent (SNP) | VAF 57/269 reads (21%) | called by muse, mutect2, varscan2
- ZNF469 | c.7092G>A p.K2364= (on ENST00000437464; = p.K2392= on NM_001367624.2) | Silent (SNP) | VAF 15/470 reads (3%) | called by muse, mutect2
- AC106741.1 | c.*39G>T | 3'UTR (SNP) | VAF 14/109 reads (13%) | catalogued as rs1339151046; called by muse, mutect2, varscan2
- CD320 | c.*205G>C | 3'UTR (SNP) | VAF 67/300 reads (22%) | called by muse, mutect2, varscan2
- CHD3 | c.5590+21G>A | Intron (SNP) | VAF 7/120 reads (6%) | catalogued as rs1172520224; called by muse, mutect2
- FAM193B | c.1076+18A>C | Intron (SNP) | VAF 50/328 reads (15%) | called by muse, mutect2, varscan2
- FGFR4 | c.1057+165_1057+166del | Intron (DEL) | VAF 80/600 reads (13%) | called by pindel, varscan2
- GYS2 | c.1890+47A>G | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- HBD | c.-29+230G>C | Intron (SNP) | VAF 41/195 reads (21%) | called by muse, mutect2, varscan2
- LINC02694 | n.107A>C | RNA (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- MT1G | c.97+82_97+84del | Intron (DEL) | VAF 65/301 reads (22%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.210-29G>T | Intron (SNP) | VAF 55/329 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158773 C>T | 5'Flank (SNP) | VAF 14/139 reads (10%) | catalogued as rs772284609; called by muse, mutect2, varscan2
- RPL4 | c.-24G>A | 5'UTR (SNP) | VAF 31/176 reads (18%) | catalogued as rs371027636; called by muse, mutect2, varscan2
- SLC2A1 | c.868-50del | Intron (DEL) | VAF 49/280 reads (18%) | called by mutect2, pindel, varscan2
- TMEM134 | c.329+28C>T | Intron (SNP) | VAF 71/329 reads (22%) | catalogued as rs201248558; called by muse, mutect2, varscan2
- TMEM258 | c.3+19G>T | Intron (SNP) | VAF 61/359 reads (17%) | called by muse, mutect2, varscan2
- USP32P3 | n.3271+886C>A | Intron (SNP) | VAF 30/470 reads (6%) | called by muse, mutect2
- VAPB | c.*4774A>G | 3'UTR (SNP) | VAF 53/286 reads (19%) | catalogued as COSV55666798; called by muse, mutect2, varscan2
- ZEB1 | c.58+43636G>T | Intron (SNP) | VAF 53/245 reads (22%) | called by muse, mutect2, varscan2
